Gene-level copy-number profile of tumor specimen TCGA-VS-A9V2-01A from TCGA case TCGA-VS-A9V2, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 29.1 years (10,637 days).
Specimen TCGA-VS-A9V2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.3b6e14c5-31d5-4828-8555-4d46c18e107a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VS-A9V2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dda1a3ed-7ca0-451f-b20a-87a55b832fef

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 2: 8,179; copy number 4: 43,621; copy number 6: 5,684; copy number 7: 2,254; copy number 12: 37; copy number 16: 31; copy number 20: 3; copy number 22: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VS-A9V2-01A-11D-A42N-01): tumor purity 0.55, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:72,371,825–72,446,623, 1 gene (within-gene range 0–4): RYBP.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 80 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:85,133,392–85,649,283, 31 genes, copy number 16: TCF7L1, TCF7L1-IT1, RNU6-674P, SNRPEP11, AC093162.1, TGOLN2, Y_RNA, PEBP1P2, RETSAT, ELMOD3, AC062037.1, Y_RNA, RN7SL113P, AC062037.2, CAPG, AC062037.3, SH2D6, Y_RNA, RN7SL251P, Y_RNA, RPSAP22, PARTICL, MAT2A, GGCX, VAMP8, RN7SL126P, VAMP5, RNF181, TMEM150A, USP39, C2orf68.
- chr11:30,323,104–30,368,646, 2 genes, copy number 20: ARL14EP, RPL12P30.
- chr11:30,425,552–30,429,268, 1 gene, copy number 20: AL353699.1.
- chr11:30,830,369–33,357,023, 45 genes, copy number 12–22 (within-gene range 2–22): DCDC1, CYCSP25, AL137804.1, DNAJC24, IMMP1L, ELP4, AC131571.1, PAX6, PAUPAR, AL035078.4, AL035078.1, AL035078.3, AL035078.2, U3, EIF4A2P5, RCN1, AL078612.1, THEM7P, AL078612.2, WT1, WT1-AS, AL049692.6, AL049692.1, AL049692.5, AL049692.3, AL049692.2, AL049692.4, EIF3M, HNRNPA3P9, CCDC73, AL049714.1, PRRG4, QSER1, Y_RNA, DEPDC7, TCP11L1, PIGCP1, LINC00294, CSTF3, CSTF3-DT, Y_RNA, RPL29P23, Y_RNA, AL136126.1, HIPK3.
- chr11:33,403,216–33,403,605, 1 gene, copy number 12: AL137161.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
